Somatic mutation profile of tumor specimen TCGA-FE-A231-01A (aliquot TCGA-FE-A231-01A-11D-A14W-08) from TCGA case TCGA-FE-A231, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 70.4 years (25,703 days).
Specimen TCGA-FE-A231-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2c762c2-05f3-4345-8128-8bc8bb43630b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FE-A231-10A (Blood Derived Normal), aliquot TCGA-FE-A231-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9801cc05-07ad-4368-a839-46dade5cee32

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCG8 | c.1868C>A p.A623E | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55393574; called by muse, mutect2, varscan2
- ATP2C2 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 34/330 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201615601; called by muse, mutect2, varscan2
- EIF2S2 | c.974G>C p.R325P | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66621631, COSV66621640; called by muse, mutect2, varscan2
- RRP8 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV54449718; called by muse, mutect2
- TLN2 | c.1971G>C p.Q657H | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1326999599, COSV60890138, COSV60890787; called by muse, mutect2, varscan2
- TRPA1 | c.2705T>C p.L902S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.198); catalogued as COSV51562765; called by muse, mutect2, varscan2
- TSHZ2 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs141167641, COSV61586883; called by muse, mutect2, varscan2
- ADAMTS2 | c.2568C>T p.Y856= | Silent (SNP) | VAF 65/139 reads (47%) | catalogued as rs769226679, COSV52363091; called by muse, mutect2, varscan2
- PANX2 | c.369C>T p.F123= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV50296448; called by muse, mutect2, varscan2
- PRDX5 | c.6A>C p.G2= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV50005610; called by muse, varscan2
